Somatic mutation profile of tumor specimen TARGET-10-PATBDJ-09A (aliquot TARGET-10-PATBDJ-09A-01D) from TARGET case TARGET-10-PATBDJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,803 days).
Specimen TARGET-10-PATBDJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0a26728-d09c-4dc2-915a-e767c4b68fb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBDJ-10A (Blood Derived Normal), aliquot TARGET-10-PATBDJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4116ff62-829f-41e1-9676-02f104bb2e4e

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Region 1, 5'Flank 1, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKZF1 | c.1204+5G>C | Splice Region (SNP) | VAF 20/75 reads (27%) | catalogued as COSV55475560; called by muse, mutect2, varscan2
- ARID3B | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs781388841, COSV60556572; called by mutect2, varscan2
- CAPN13 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs769225286, COSV54428691; called by muse, mutect2, varscan2
- DNAJB13 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs369265644; called by muse, mutect2, varscan2
- KCTD8 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63585822; called by muse, mutect2, varscan2
- KMT2A | c.3200G>A p.R1067Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63282607; called by muse, mutect2, varscan2
- NOTCH1 | c.6814C>T p.R2272C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752505638, COSV53032064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH7 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.867); catalogued as rs1380743687, COSV62336907; called by muse, mutect2, varscan2
- PDZD2 | c.5159G>A p.S1720N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56851964; called by muse, mutect2, varscan2
- RHOA | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69041804, COSV69042801; called by muse, mutect2, varscan2
- SF3B1 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59207991; called by muse, mutect2, varscan2
- TRDN | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.643); catalogued as rs777613395, COSV62114336; called by muse, mutect2, varscan2
- WNK3 | c.4877T>A p.L1626Q | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV63612306; called by muse, mutect2, varscan2
- ZBTB33 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58533151; called by muse, mutect2, varscan2
- RFX7 | c.2203del p.S735Afs*13 (on ENST00000559447 / NM_001368074.1; = p.S832Afs*13 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/131 reads (8%) | called by mutect2, pindel*
- ALG1L | c.60C>T p.R20= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs763318007, COSV61075203; called by muse, mutect2, varscan2
- IL27 | c.489G>A p.P163= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs555159508; called by muse, mutect2, varscan2
- SEH1L | c.465G>A p.L155= | Silent (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509298 C>T | 5'Flank (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-677G>A | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1352377965; called by muse, mutect2
- SSPOP | n.4321G>A | RNA (SNP) | VAF 9/22 reads (41%) | catalogued as rs1420045458, COSV50486564; called by muse, mutect2, varscan2
